TCGA case TCGA-A2-A0EQ — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Walter Reed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2192c1db-4718-4254-ba42-3ae7f30ad5a8

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 64.5 years (23,543 days); Year of diagnosis: 2004; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0 (i-); AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2; Micrometastasis present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 84 days; Days to treatment end: 146 days; Number of cycles: 4; Treatment dose: 4,872 mg; Prescribed dose: 1218; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 84 days; Days to treatment end: 146 days; Number of cycles: 4; Treatment dose: 488 mg; Prescribed dose: 122; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 167 days; Days to treatment end: 167 days; Number of cycles: 1; Treatment dose: 355 mg; Prescribed dose: 355; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 203 days; Days to treatment end: 251 days; Treatment dose: 6,040 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Trastuzumab; Treatment intent type: Adjuvant; Days to treatment start: 229 days; Days to treatment end: 586 days (1.6 years); Number of cycles: 22; Treatment dose: 10,543 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: AE37 Peptide/GM-CSF Vaccine; Days to treatment start: 679 days (1.9 years); Days to treatment end: 796 days (2.2 years); Number of cycles: 6; Treatment dose: 3,000 ug; Prescribed dose: 500; Prescribed dose units: ug.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Re-Excision; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Involved; Treatment anatomic sites: Breast.

Follow-up (2 entries)
- Days to follow up: 2,053 days (5.6 years); Disease response: Tumor Free.
- Days to follow up: 2,426 days (6.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (FISH): 1.1; Specialized molecular test: Signal ratio.
- ERBB2 (IHC): Positive; Staining intensity value: 3+.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Negative; Staining intensity value: 0; Test value range: <10%.
- PGR (IHC): Negative; Staining intensity value: 0; Test value range: <10%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A2-A0EQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 600 mg.
  Slide TCGA-A2-A0EQ-01A-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A2-A0EQ-01A-01-BSA: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A2-A0EQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A2-A0EQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Her2 cent17 ratio: 1.1; Axillary staging method other: Sentinel lymph node and non-sentinel lymph node biopsy; Surgical procedure first: Lumpectomy; Surgery for positive margins: Lumpectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: Yes; Er IHC score: 0; Her2 IHC score: 3+; Method initial path diagnosis: Core needle biopsy; Prospective collection: No; Retrospective collection: Yes; Er status IHC Percent Positive: <10%; Pr status IHC percent positive: <10%; Pr positivity IHC intensity score: 0.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Adriamycin.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 4; Pharmaceutical therapy drug name: Herceptin.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 4: Regimen number: 3.
- Drug treatment 5: Regimen number: 5; Pharmaceutical therapy drug name: AE-37; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Cancer Vaccine Trial.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,426 days; disease-specific survival: no event (censored), 2,426 days; disease-free interval: no event (censored), 2,426 days; progression-free interval: no event (censored), 2,426 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A2-A0EQ-01A-11D-A036-01): tumor purity 0.38, ploidy 2.66, whole-genome doublings 1.
